Somatic mutation profile of cancer-model specimen HCM-WCMC-0790-C67-85B (3D Organoid; aliquot HCM-WCMC-0790-C67-85B-01D-A905-36), derived from the primary tumor of HCMI case HCM-WCMC-0790-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 62.4 years (22,784 days).
Specimen HCM-WCMC-0790-C67-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae52e942-bffd-402c-b0ea-9af1d3c5e152.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0790-C67-10A (Blood Derived Normal), aliquot HCM-WCMC-0790-C67-10A-01D-A905-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36a91495-c0df-4250-a20b-d2581e110456

The open-access MAF lists 131 somatic variants for this specimen: 96 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 31, Nonsense Mutation 6, Frame Shift Del 5, Intron 2, In Frame Del 2, 5'UTR 1, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 122/360 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- USH2A | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 124/393 reads (32%) | catalogued as rs111033334, CM071124, COSV56408694; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP13A2 | c.880C>T p.R294W | Missense Mutation (SNP) | VAF 401/431 reads (93%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs144898239; called by muse, mutect2, varscan2
- ATP8B3 | c.745G>A p.V249I | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.627); catalogued as rs186171636; called by muse, mutect2, varscan2
- B4GALNT4 | c.2957G>A p.R986Q | Missense Mutation (SNP) | VAF 208/419 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.402); catalogued as rs1484353641; called by muse, mutect2, varscan2
- CBLN4 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 66/698 reads (9%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as rs769675747; called by muse, mutect2
- CCIN | c.1271G>A p.R424K | Missense Mutation (SNP) | VAF 375/675 reads (56%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV58724647; called by muse, mutect2, varscan2
- COL22A1 | c.4682C>A p.P1561H | Missense Mutation (SNP) | VAF 269/858 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100280584; called by muse, mutect2, varscan2
- COL26A1 | c.278T>G p.V93G | Missense Mutation (SNP) | VAF 26/430 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.299); catalogued as COSV100562051; called by muse, mutect2
- COL4A6 | c.3593G>T p.G1198V | Missense Mutation (SNP) | VAF 168/168 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100563203; called by muse, mutect2, varscan2
- COPA | c.2652_2654del p.E884del | In Frame Del (DEL) | VAF 48/382 reads (13%) | catalogued as rs778904236; called by pindel, varscan2
- EGFR | c.1075T>C p.F359L | Missense Mutation (SNP) | VAF 160/283 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV51787534; called by muse, mutect2, varscan2
- FAM193B | c.2351G>A p.R784Q | Missense Mutation (SNP) | VAF 63/317 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs745509573; called by muse, mutect2, varscan2
- GALNT6 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 309/309 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV62542292; called by muse, mutect2, varscan2
- GCN1 | c.4682C>T p.A1561V | Missense Mutation (SNP) | VAF 328/726 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56112442; called by muse, mutect2, varscan2
- GLI2 | c.2617C>T p.R873W (on ENST00000361492 / NM_001374353.1; = p.R890W on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 468/536 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs775833166; called by muse, varscan2
- IER2 | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 77/275 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs963727279, COSV52847526; called by muse, mutect2, varscan2
- KLF7 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 386/386 reads (100%) | SIFT tolerated (0.33); PolyPhen benign (0.019); catalogued as rs752417303; called by muse, mutect2, varscan2
- KMT5B | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 134/278 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as rs1164268086, COSV58564146; called by muse, mutect2, varscan2
- LILRB2 | c.283C>T p.R95* | Nonsense Mutation (SNP) | VAF 484/799 reads (61%) | catalogued as rs746435174, COSV58747816; called by muse, varscan2
- LPAR3 | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 518/559 reads (93%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as rs745349747, COSV65453207; called by muse, mutect2, varscan2
- MUC17 | c.9031C>T p.P3011S | Missense Mutation (SNP) | VAF 220/386 reads (57%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.857); catalogued as rs757084416; called by muse, mutect2, varscan2
- MYH1 | c.448G>A p.E150K | Missense Mutation (SNP) | VAF 384/386 reads (99%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1489348825; called by muse, mutect2, varscan2
- NECAP2 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 698/742 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as rs189133321; called by muse, mutect2, varscan2
- NPIPB11 | c.3340C>T p.R1114W | Missense Mutation (SNP) | VAF 66/156 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1461538286; called by mutect2, varscan2
- OLAH | c.760A>G p.I254V (on ENST00000378228 / NM_001039702.3; = p.I307V on NM_018324.3) | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs1224743650; called by muse, mutect2
- OXR1 | c.578G>A p.G193D (on ENST00000442977 / NM_001198532.1; = p.G192D on NM_018002.3) | Missense Mutation (SNP) | VAF 66/770 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs540340584; called by muse, mutect2
- P4HA3 | c.751C>G p.R251G | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.201); catalogued as COSV59043740, COSV59044083; called by muse, mutect2, varscan2
- PLCD1 | c.911A>G p.H304R | Missense Mutation (SNP) | VAF 114/448 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as rs1398394701; called by muse, mutect2, varscan2
- PSMA1 | c.577C>T p.R193C | Missense Mutation (SNP) | VAF 106/274 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs201085140; called by muse, varscan2
- RAB6B | c.28C>A p.P10T | Missense Mutation (SNP) | VAF 91/333 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV53312848; called by muse, mutect2, varscan2
- RB1 | c.2536del p.Q846Rfs*3 | Frame Shift Del (DEL) | VAF 84/114 reads (74%) | catalogued as CM025392, COSV99926164; called by mutect2, pindel, varscan2
- RNFT1 | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 239/434 reads (55%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768994695; called by muse, mutect2, varscan2
- RPTOR | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 190/430 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs781427409; called by muse, mutect2, varscan2
- SEC14L1 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 53/430 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs781370833, COSV66720682; called by muse, mutect2, varscan2
- SLC52A1 | c.906C>A p.S302R | Missense Mutation (SNP) | VAF 32/672 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1379635053; called by muse, mutect2
- THBS2 | c.1236C>A p.S412R | Missense Mutation (SNP) | VAF 17/394 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV64682534; called by muse, mutect2
- TPO | c.2463C>G p.F821L | Missense Mutation (SNP) | VAF 364/408 reads (89%) | SIFT deleterious (0.01); PolyPhen benign (0.389); catalogued as COSV61109965; called by muse, mutect2, varscan2
- UNC13C | c.4277C>T p.S1426L | Missense Mutation (SNP) | VAF 154/154 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.335); catalogued as rs1177997616, COSV52883187; called by muse, mutect2, varscan2
- URB1 | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 259/555 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs780136755; called by muse, mutect2, varscan2
- VPS25 | c.7A>G p.M3V | Missense Mutation (SNP) | VAF 155/384 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.11); catalogued as rs1036053889; called by muse, mutect2, varscan2
- ZFPM2 | c.3037G>A p.E1013K | Missense Mutation (SNP) | VAF 288/707 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.024); catalogued as rs200487685; called by muse, mutect2, varscan2
- ZNF536 | c.2852G>T p.G951V | Missense Mutation (SNP) | VAF 166/446 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV100836070, COSV62824295; called by muse, mutect2, varscan2
- ACO2 | c.1855A>T p.I619F | Missense Mutation (SNP) | VAF 446/447 reads (100%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ALPK2 | c.4586del p.K1529Rfs*6 | Frame Shift Del (DEL) | VAF 33/241 reads (14%) | called by mutect2, pindel, varscan2
- APAF1 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 198/198 reads (100%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ASTE1 | c.589T>A p.C197S | Missense Mutation (SNP) | VAF 201/287 reads (70%) | SIFT tolerated (0.05); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ATP1B4 | c.495C>G p.F165L (on ENST00000218008 / NM_001142447.3; = p.F161L on NM_012069.5) | Missense Mutation (SNP) | VAF 289/291 reads (99%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- BCAS1 | c.692C>G p.S231* | Nonsense Mutation (SNP) | VAF 275/541 reads (51%) | called by muse, mutect2, varscan2
- BORA | c.1843G>A p.D615N (on ENST00000613797; = p.D540N on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 192/376 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); called by muse, mutect2
- C3AR1 | c.707G>A p.R236K | Missense Mutation (SNP) | VAF 312/653 reads (48%) | SIFT tolerated (0.34); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CAMK4 | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 164/229 reads (72%) | SIFT tolerated (0.82); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- CNTN1 | c.2572C>T p.Q858* | Nonsense Mutation (SNP) | VAF 329/330 reads (100%) | called by muse, mutect2, varscan2
- DNER | c.1387C>A p.P463T | Missense Mutation (SNP) | VAF 336/336 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- EIF3H | c.206G>A p.G69D | Missense Mutation (SNP) | VAF 76/1038 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.396); called by muse, mutect2
- EIF4G1 | c.3655G>T p.D1219Y (on ENST00000346169 / NM_198241.3; = p.D1024Y on NM_004953.5) | Missense Mutation (SNP) | VAF 54/256 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- ELOA2 | c.71C>A p.P24Q | Missense Mutation (SNP) | VAF 60/215 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPYC | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- FAM216B | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO7 | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 262/750 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- GARRE1 | c.721_728delinsC p.R241Qfs*28 | Frame Shift Del (DEL) | VAF 197/370 reads (53%) | called by pindel, varscan2*
- GGN | c.946G>A p.D316N | Missense Mutation (SNP) | VAF 430/671 reads (64%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GPR3 | c.410C>T p.S137F | Missense Mutation (SNP) | VAF 509/513 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIA1 | c.391G>T p.D131Y | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- HTR1A | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 311/311 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ITGAX | c.1271C>G p.A424G | Missense Mutation (SNP) | VAF 98/637 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KIR3DL3 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 137/862 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- MTMR3 | c.3399G>T p.W1133C | Missense Mutation (SNP) | VAF 72/686 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MZT1 | c.22G>C p.G8R | Missense Mutation (SNP) | VAF 76/438 reads (17%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NAALAD2 | c.2050C>A p.P684T | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NCAN | c.2263G>C p.G755R | Missense Mutation (SNP) | VAF 199/199 reads (100%) | SIFT tolerated (0.2); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- NEK5 | c.400A>T p.I134F | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- NLRP11 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 91/261 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- NPHP3 | c.2551T>C p.Y851H | Missense Mutation (SNP) | VAF 76/276 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR4Q2 | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 53/232 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- PGM5 | c.848G>T p.G283V | Missense Mutation (SNP) | VAF 227/232 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, varscan2
- PLEKHD1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 330/330 reads (100%) | SIFT tolerated (0.39); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PLXNB2 | c.918_931del p.P307Lfs*28 | Frame Shift Del (DEL) | VAF 465/487 reads (95%) | called by mutect2, pindel, varscan2
- POTEB3 | c.1687G>C p.E563Q | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.251); called by muse, mutect2
- PRMT1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 223/694 reads (32%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PURB | c.425_442del p.R142_R147del | In Frame Del (DEL) | VAF 141/402 reads (35%) | called by mutect2, pindel, varscan2
- RESF1 | c.4808C>A p.S1603* | Nonsense Mutation (SNP) | VAF 66/702 reads (9%) | called by muse, mutect2
- RYR1 | c.8817-1G>A p.X2939_splice | Splice Site (SNP) | VAF 153/233 reads (66%) | called by muse, mutect2, varscan2
- SELENOM | c.413A>G p.E138G | Missense Mutation (SNP) | VAF 27/844 reads (3%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); called by muse, mutect2
- SLC44A3 | c.1783C>A p.L595M (on ENST00000271227 / NM_001114106.3; = p.L547M on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 219/426 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A1 | c.269C>T p.P90L | Missense Mutation (SNP) | VAF 481/482 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- SLIT2 | c.3495A>G p.I1165M | Missense Mutation (SNP) | VAF 38/227 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SNRPA | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 194/516 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- SPEM2 | c.553C>A p.L185M | Missense Mutation (SNP) | VAF 44/727 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); called by muse, mutect2
- TMEM131L | c.1240A>G p.N414D | Missense Mutation (SNP) | VAF 16/370 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- TP53 | c.142_149del p.D48* | Frame Shift Del (DEL) | VAF 392/409 reads (96%) | called by mutect2, pindel, varscan2
- TRHR | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 304/831 reads (37%) | called by muse, mutect2, varscan2
- TTC33 | c.227C>T p.S76L | Missense Mutation (SNP) | VAF 39/167 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ZNF106 | c.5462C>T p.S1821F | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- ZNF670 | c.49G>C p.E17Q | Missense Mutation (SNP) | VAF 128/405 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF99 | c.833T>C p.I278T | Missense Mutation (SNP) | VAF 49/123 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ANGPT1 | c.1233A>C p.T411= | Silent (SNP) | VAF 54/757 reads (7%) | called by muse, mutect2
- BAHCC1 | c.7401C>A p.S2467= | Silent (SNP) | VAF 89/470 reads (19%) | catalogued as COSV57026340; called by mutect2, varscan2
- BEGAIN | c.1080G>A p.L360= | Silent (SNP) | VAF 477/477 reads (100%) | called by muse, mutect2, varscan2
- BPNT2 | c.153G>A p.G51= | Silent (SNP) | VAF 317/1340 reads (24%) | catalogued as rs771799837; called by muse, mutect2, varscan2
- CNBD1 | c.315T>G p.P105= | Silent (SNP) | VAF 37/868 reads (4%) | called by muse, mutect2
- CRYBB1 | c.690T>G p.R230= | Silent (SNP) | VAF 94/759 reads (12%) | called by muse, mutect2, varscan2
- DMGDH | c.186G>A p.V62= | Silent (SNP) | VAF 338/338 reads (100%) | called by muse, varscan2
- DNAH17 | c.5211C>T p.L1737= | Silent (SNP) | VAF 195/419 reads (47%) | catalogued as rs1331566417; called by muse, mutect2
- DOCK2 | c.5346C>G p.R1782= | Silent (SNP) | VAF 24/480 reads (5%) | called by muse, mutect2
- GLT8D1 | c.210C>T p.I70= | Silent (SNP) | VAF 278/434 reads (64%) | catalogued as rs763141956; called by muse, mutect2, varscan2
- LANCL2 | c.1119C>T p.N373= | Silent (SNP) | VAF 196/358 reads (55%) | catalogued as rs540998427, COSV99634509; called by muse, mutect2, varscan2
- LYPLA1 | c.105C>T p.H35= | Silent (SNP) | VAF 191/449 reads (43%) | catalogued as rs200672484; called by muse, mutect2, varscan2
- MEIG1 | c.60G>A p.E20= | Silent (SNP) | VAF 195/371 reads (53%) | catalogued as rs1009477872; called by muse, mutect2, varscan2
- MRTFB | c.1875C>A p.V625= | Silent (SNP) | VAF 227/620 reads (37%) | called by muse, mutect2, varscan2
- MYH11 | c.2103C>T p.C701= | Silent (SNP) | VAF 288/488 reads (59%) | called by muse, mutect2, varscan2
- NKX2-1 | c.294G>C p.P98= | Silent (SNP) | VAF 424/424 reads (100%) | called by muse, mutect2, varscan2
- NRROS | c.144C>T p.L48= | Silent (SNP) | VAF 234/333 reads (70%) | catalogued as rs146517885, COSV60745090; called by muse, mutect2, varscan2
- OR10C1 | c.702C>T p.G234= (on ENST00000622521; = p.G232= on NM_013941.3) | Silent (SNP) | VAF 296/579 reads (51%) | catalogued as COSV65823152; called by muse, mutect2, varscan2
- OR10G9 | c.510C>T p.P170= | Silent (SNP) | VAF 199/463 reads (43%) | called by muse, mutect2, varscan2
- PANK1 | c.1275C>T p.Y425= (on ENST00000307534 / NM_148977.2; = p.Y200= on NM_138316.4) | Silent (SNP) | VAF 54/251 reads (22%) | called by muse, mutect2, varscan2
- PKDCC | c.783C>T p.R261= | Silent (SNP) | VAF 51/540 reads (9%) | called by muse, mutect2
- PLEC | c.5652G>T p.T1884= (on ENST00000322810 / NM_201380.4; = p.T1774= on NM_000445.5) | Silent (SNP) | VAF 64/1316 reads (5%) | catalogued as rs1216335768; called by muse, mutect2
- PRDM14 | c.633C>T p.P211= | Silent (SNP) | VAF 375/1022 reads (37%) | catalogued as COSV52574908; called by muse, mutect2, varscan2
- PXDN | c.1515C>T p.V505= | Silent (SNP) | VAF 12/385 reads (3%) | called by muse, mutect2
- SERPINE2 | c.222G>A p.K74= | Silent (SNP) | VAF 304/305 reads (100%) | catalogued as COSV51460592; called by muse, mutect2, varscan2
- SHC2 | c.1095C>G p.L365= | Silent (SNP) | VAF 167/167 reads (100%) | called by muse, mutect2, varscan2
- SLC15A4 | c.534C>T p.F178= | Silent (SNP) | VAF 332/625 reads (53%) | called by muse, mutect2, varscan2
- ST14 | c.2205C>T p.A735= | Silent (SNP) | VAF 274/559 reads (49%) | catalogued as rs1197469047; called by muse, mutect2, varscan2
- SVIL | c.4128G>A p.Q1376= (on ENST00000355867 / NM_021738.3; = p.Q950= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 59/722 reads (8%) | called by muse, mutect2
- TC2N | c.954G>A p.K318= | Silent (SNP) | VAF 314/314 reads (100%) | catalogued as rs748255773; called by muse, mutect2, varscan2
- THRAP3 | c.927G>A p.L309= | Silent (SNP) | VAF 32/434 reads (7%) | catalogued as COSV63566635; called by muse, mutect2
- C12orf76 | n.372C>G | RNA (SNP) | VAF 362/753 reads (48%) | called by muse, mutect2, varscan2
- FARP1 | c.1414+223C>T | Intron (SNP) | VAF 128/284 reads (45%) | called by muse, mutect2, varscan2
- KAZN | c.249+124018G>C | Intron (SNP) | VAF 16/342 reads (5%) | called by muse, mutect2
- PALM2AKAP2 | c.-95C>G | 5'UTR (SNP) | VAF 38/212 reads (18%) | called by muse, mutect2, varscan2
